TARGET case TARGET-40-NAASJI — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/92c1307d-3ec9-5752-875e-67775c8d58d7

Demographics
Sex at birth: male; Age at index: 19 years; Vital status: Dead; Days to death: 388 days (1.1 years).

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.4; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Classification of tumor: primary; Age at diagnosis: 19.4 years (7,074 days); Year of diagnosis: 2007; Metastasis at diagnosis: No Metastasis; Days to last follow up: 388 days (1.1 years).
   Treatment given: Protocol identifier: IHRT.

Follow-up (1 entry)
- Days to follow up: 388 days (1.1 years); Days to first event: 388 days (1.1 years); First event: Death; Year of follow up: 2008.

Biospecimens (2 samples)
- Sample TARGET-40-NAASJI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAASJI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 388
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Other
- Specific tumor site: Sacrum
- Primary site progression: No
